Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZN, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZN-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Collected: _____
Received: _____

Case type: Surgical Case
Accession: _____

DOB: _____
Physician: _____

DIAGNOSIS

- (A) CONFIRM PARATHYROID:

Parathyroid tissue present.
- (B) THYROID AND LEVEL 6 CONTENTS:

PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Left lobe

Multi-focal: No

Size = 1.3 cm

Extrathyroidal extension: Present, extending into fibroadipose tissue

Lymphovascular invasion: Present

Resection Margins: Negative

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN 2 OF 13 LYMPH NODES

Location: Central, neck

Extracapsular extension: Absent
- (C) LEFT LEVELS 2A, 3, 4 AND 5:

METASTATIC PAPILLARY THYROID CARCINOMA IN 4 OF 42 LYMPH NODES

Extracapsular extension: Absent

ICD-O-3
CQCF: carcinoma, papillary, thyroid 8260/3
Path: carcinoma, papillary, follicular variant 8340/3
Site: thyroid, NOS
C73.9
6/17/12

GROSS DESCRIPTION

- (A) CONFIRM PARATHYROID - A tan soft tissue fragment (0.2 x 0.1 x 0.1 cm). A touch prep is made and specimen is entirely submitted for frozen in A.
- *FS/DX: PARATHYROID GLAND.
- (B) THYROID AND LEVEL 6 CONTENTS - A total thyroidectomy consisting of right lobe (5.2 x 2.4 x 2.2 cm) and left lobe (4.8 x 2.2 x 1.6 cm) also in the container is a cystic hemorrhagic nodule (0.6 cm x diameter). The right lobe is unremarkable. The isthmus is unremarkable. The superior portion of the left lobe has a soft pink-tan multinodular focus (1.3 x 1.1 x 0.8 cm) which abuts the edge of the thyroid and is covered by loosely adherent soft tissue over the anterior surface. The remainder of the left lobe is unremarkable.
- SECTION CODE: B1-B3, right lobe representative from superior to inferior; B4, isthmus; B5-B7, superior left lobe with nodule; B8-B10, additional left lobe; B11, cystic nodule bisected; B12-B14, multiple lymph nodes from central adipose tissue in each cassette.
- (C) LEFT LEVELS 2A, 3, 4 AND 5 - Fibroadipose tissue (7.5 x 5.5 x 1.0 cm). Multiple lymph nodes are identified ranging from (0.1 x 0.1 x 0.1 to 1.5 x 1.0 x 0.7 cm).
- SECTION CODE: C1, one lymph node from level 2A; C2, one lymph node from level 3; C3-C5, lymph node from level 4 (C3, five lymph nodes; C4, four lymph nodes; C5, one lymph node, serially sectioned); C6-C13, lymph node from level 5 (C6-C12, each containing four lymph nodes; C13, two lymph nodes)

CLINICAL HISTORY

[page 2 of 2]
Surgical Pathology Report

DOB
Physician:

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession

Papillary thyroid carcinoma.

SNOMED CODES

T-C4200, M-80506, T-B6000, M-83403, T-C4200, M-80506,

"Some tests reported here may have been developed and performance characteristics determined by
approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Entire report and diagnosis completed by:

Page 2 of 2

Surgical Pathology Report

File under: Pathology

Source: NCI Genomic Data Commons file d2178443-e80f-4db7-8e36-beda608152df (TCGA-EL-A3ZN.88D047C4-3144-4627-A7E8-2035D5C14852.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).